Surgical pathology report (de-identified scan), TCGA case TCGA-50-5055, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-50-5055-01A (Primary Tumor).

FINAL DIAGNOSIS:**Summary Statement**

The left lower lobe wedge resection demonstrates a 2.5 cm invasive moderately differentiated adenocarcinoma without visceral pleural invasion and involving one of five N1 lymph nodes. All margins free. Pathologic stage T1, N1, MX.

PART 1: LUNG, LEFT LOWER LOBE, SEGMENTAL RESECTION -

- A. MODERATELY DIFFERENTIATED ADENOCARCINOMA WITH ACINAR, PAPILLARY AND BRONCHIOLOALVEOLAR FEATURES. DIAMETER 2.5 CM. FOCAL ANGIOLYMPHATIC INVASION IDENTIFIED. NO EVIDENCE OF VISCERAL PLEURAL INVASION. MARKED HOST LYMPHOCYTIC RESPONSE. ALL MARGINS FREE. PATHOLOGIC STAGE T1, N1, MX.
- B. EMPHYSEMATOUS CHANGE WITH FOCAL ORGANIZING PNEUMONIA.
- C. MULTIPLE SMALL CARCINOID TUMORLETS.

**PART 2: LUNG, INFERIOR LEFT LOWER LOBE NODULE, WEDGE RESECTION -
PULMONARY HAMARTOMA. MARGINS FREE.****PART 3: INTERLOBAR LYMPH NODE, BIOPSY -**

THREE FRAGMENTS OF LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA.

PART 4: LYMPH NODE, POSTERIOR HILAR LYMPH NODE, BIOPSY -

ONE OF TWO LYMPH NODES WITH METASTATIC ADENOCARCINOMA.

PART 5: LYMPH NODE, AP WINDOW LYMPH NODE, BIOPSY -

SOLITARY FRAGMENT OF LYMPH NODE WITH NO EVIDENCE OF METASTATIC ADENOCARCINOMA.

Source: NCI Genomic Data Commons file 1b4b446e-959d-4acf-a9d5-d246d8dc294c (TCGA-50-5055.847A0C64-CD3E-4A99-A6F7-B4BA1636ADA1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).